Somatic mutation profile of tumor specimen MP2PRT-PAVPYR-TBP1-A (aliquot MP2PRT-PAVPYR-TBP1-A-1-0-D-A821-36) from MP2PRT case MP2PRT-PAVPYR, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.9 years (1,052 days).
Specimen MP2PRT-PAVPYR-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d026d09a-c2f0-4606-9b64-d25c407f4836.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVPYR-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVPYR-NB1-A-1-0-D-A821-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0cbcb936-2177-44be-9c5e-52fad57d2db9

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PNPT1 | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 19/193 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs774425075; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FRRS1 | c.832C>T p.R278* | Nonsense Mutation (SNP) | VAF 30/258 reads (12%) | catalogued as rs932403157, COSV54920643; called by muse, mutect2, varscan2
- LRIT3 | c.277G>A p.V93M | Missense Mutation (SNP) | VAF 46/394 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1479270315, COSV100015914; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRIK1 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- OR56B4 | c.899T>C p.M300T | Missense Mutation (SNP) | VAF 66/422 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPP1R15A | c.1912T>A p.S638T | Missense Mutation (SNP) | VAF 103/561 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- GPR156 | c.894T>G p.V298= | Silent (SNP) | VAF 61/359 reads (17%) | called by muse, mutect2, varscan2
- PIGL | c.378C>T p.H126= | Silent (SNP) | VAF 57/401 reads (14%) | catalogued as COSV99848822; called by muse, mutect2, varscan2
